Gene-level copy-number profile of tumor specimen HTMCP-02-03-01018-01A from CGCI case HTMCP-02-03-01018, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.1 years (19,013 days).
Specimen HTMCP-02-03-01018-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 12793ee1-cc1a-4a3e-b123-b2e3b95c4d20.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-03-01018-11B (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/572ab61e-6f6e-409b-a23f-d1adf7c71afd

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 399; copy number 1: 31,875; copy number 2: 25,796; copy number 3: 226; copy number 4: 616.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–1): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:7,836,436–8,049,267, 17 genes: DEFB104A, SPAG11A, DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, FAM66E, AC130365.1, USP17L8, USP17L3, DEFB109C, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.1.
- chr8:8,086,022–8,116,949, 4 genes: AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr8:12,182,096–12,436,343, 16 genes (within-gene range 0–1): FAM86B1, AC145124.1, ENPP7P12, DEFB131D, DEFB130A, RNA5SP254, DEFB108E, ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2.
- chr9:41,890,314–42,499,134, 14 genes: CNTNAP3B, RBM17P3, CR788268.1, RN7SL343P, SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6.
- chr9:64,369,394–64,765,535, 14 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2.
- chr9:66,721,158–66,932,141, 5 genes: ATP5F1AP10, SDR42E1P4, FKBP4P8, ZNF658, BX664608.1.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–1): ACOT1, NT5CP2.
- chr14:73,567,620–73,582,918, 3 genes: ACOT2, NT5CP1, AC005225.4.
- chr17:41,101,502–41,118,373, 3 genes (within-gene range 0–1): KRTAP4-16, KRTAP4-9, KRTAP4-11.
- chr20:30,484,925–30,816,274, 4 genes: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 842 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 679 genes, copy number 3–4 (broad region; genes not listed).
- chr10:47,365,496–47,619,480, 13 genes, copy number 3: ZNF488, ANXA8, AL591684.3, FAM25G, AL591684.1, AGAP9, AL591684.2, RNA5SP312, BMS1P2, BX547991.1, DUSP8P1, CTSLP2, LINC02675.
- chr14:33,924,227–34,462,774, 1 gene, copy number 3 (within-gene range 1–3): EGLN3.
- chr14:34,416,687–37,172,606, 77 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr16:16,499,533–16,664,135, 2 genes, copy number 3: AC136431.1, AC136619.2.
- chr16:59,166,951–65,938,453, 48 genes, copy number 3: AC092121.1, RNU4-58P, DUXAP11, APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1, AC092131.1, PPIAP48, AC009101.1, CDH11, AC010533.1, LINC02126, AC009055.2, AC009055.1, LINC00922, AC092138.2, AC092138.1, AC022164.1, AC025281.1.
- chr16:74,332,402–74,421,953, 5 genes, copy number 3 (within-gene range 2–3): AC009053.1, AC009053.2, NPIPB15, AC009053.4, CLEC18B.
- chr16:76,107,283–76,928,169, 13 genes, copy number 3: AC099511.1, AC010528.1, RPL18P13, AC010528.2, CNTNAP4, AC106741.1, RN7SKP233, SNORD33, AC108125.1, LINC02125, AC106729.1, MIR4719, AC106734.1.
- chr17:46,372,855–46,555,650, 4 genes, copy number 3–4: NSFP1, RDM1P2, LRRC37A2, RN7SL199P.

Autosomal genes at a single copy (total copy number 1): 29,330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
